FM case AD131 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/01f2fb59-7b16-4442-aedb-9a15aae5b015

Male, 68.1 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the parotid gland. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Tumor.
